Somatic mutation profile of tumor specimen TCGA-LN-A4MR-01A (aliquot TCGA-LN-A4MR-01A-11D-A28B-09) from TCGA case TCGA-LN-A4MR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.9 years (21,142 days).
Specimen TCGA-LN-A4MR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 636e6ed8-34bc-42c8-89a5-45960b7e9996.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4MR-10A (Blood Derived Normal), aliquot TCGA-LN-A4MR-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d0de436-ec55-421c-adfd-0e99a4a951bd

The open-access MAF lists 157 somatic variants for this specimen: 125 protein-altering or splice-affecting, 32 silent.
By variant classification: Missense Mutation 97, Silent 32, Nonsense Mutation 15, Splice Site 5, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 2, Translation Start Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 29/122 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA10 | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs760811449; called by muse, mutect2, varscan2
- ABCA3 | c.4684G>C p.E1562Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV57053431; called by muse, mutect2, varscan2
- ARHGAP26 | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs775284912, COSV50832978, COSV99189530; called by muse, mutect2, varscan2
- C1QC | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs750272291; called by muse, mutect2, varscan2
- CACNA1B | c.6700G>T p.E2234* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99500266; called by muse, mutect2, varscan2
- CASP8 | c.1098G>T p.Q366H (on ENST00000432109 / NM_033355.3; = p.Q383H on NM_001228.4) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0.091); catalogued as COSV51857704; called by muse, varscan2
- CASP8 | c.1183G>C p.D395H (on ENST00000432109 / NM_033355.3; = p.D412H on NM_001228.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV51856439; called by muse, varscan2
- CCDC34 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV58725552; called by muse, mutect2, varscan2
- CD22 | c.901A>G p.K301E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as rs1438294364; called by muse, mutect2, varscan2
- CD38 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56891573; called by muse, mutect2, varscan2
- CGN | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as rs376940080; called by muse, mutect2, varscan2
- CIZ1 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as rs767189940, COSV52970828; called by muse, mutect2, varscan2
- CYP2B6 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1315971029, COSV100137569, COSV57842978; called by muse, mutect2, varscan2
- DYNC2H1 | c.11045G>C p.R3682T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100517710; called by muse, mutect2, varscan2
- EXOC8 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV50480335; called by muse, mutect2, varscan2
- H3C2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV52517730, COSV52518686, COSV99451691; called by muse, mutect2, varscan2
- HEATR6 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV51744740; called by muse, mutect2, varscan2
- HEYL | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | catalogued as rs753352796, COSV65722125; called by muse, mutect2, varscan2
- HPF1 | c.789G>C p.E263D | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1322451587, COSV66422146; called by muse, mutect2, varscan2
- HYDIN | c.14992G>A p.E4998K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV101125219, COSV66638014; called by muse, mutect2, varscan2
- IGFL2 | c.244G>C p.D82H (on ENST00000377693 / NM_001135113.2; = p.D93H on NM_001002915.2) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV66616557, COSV66616579; called by muse, mutect2, varscan2
- IL1B | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV99641942; called by muse, mutect2, varscan2
- IL1B | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV54522852, COSV54523054; called by muse, mutect2, varscan2
- LEPR | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs868409551, COSV60747668, COSV60753134; called by muse, mutect2, varscan2
- LYST | c.6298A>G p.M2100V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as rs942649589; called by muse, mutect2, varscan2
- MAST2 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200211912; called by muse, mutect2, varscan2
- MED1 | c.2449C>T p.Q817* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100328167; called by muse, mutect2, varscan2
- NDN | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.848); catalogued as rs776854811; called by muse, mutect2, varscan2
- NEURL4 | c.3758C>T p.S1253F | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs1322379036; called by muse, mutect2, varscan2
- NGEF | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs572634482, COSV50935521; called by muse, mutect2, varscan2
- NSD1 | c.6358G>T p.E2120* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV61773903; called by muse, mutect2, varscan2
- OR1M1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs144608760; called by muse, mutect2, varscan2
- PARP4 | c.1446C>T p.L482= | Splice Region (SNP) | VAF 21/81 reads (26%) | catalogued as COSV67961710; called by muse, varscan2
- PCDHGA7 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs753215361, COSV53943132; called by muse, mutect2, varscan2
- PDCL | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1043234018; called by muse, mutect2, varscan2
- PDLIM5 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs750811930; called by mutect2, varscan2
- PIGW | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs754301297; called by muse, mutect2
- PLEKHN1 | c.1379G>A p.R460Q (on ENST00000379409; = p.R408Q on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs1180400410; called by mutect2, varscan2
- PMS2 | c.1864A>T p.M622L | Missense Mutation (SNP) | VAF 52/86 reads (60%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs370853512, CM1111596, COSV56219821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSG2 | c.709+1G>T p.X237_splice | Splice Site (SNP) | VAF 42/218 reads (19%) | catalogued as rs148538148, COSV61545390; called by muse, mutect2, varscan2
- PTEN | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV64296645, COSV64299332; called by muse, mutect2
- SERINC3 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as rs1480507623; called by muse, mutect2, varscan2
- SGIP1 | c.857C>A p.P286Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52777636; called by muse, mutect2, varscan2
- SSPN | c.430del p.A144Pfs*38 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as COSV54382279; called by mutect2, pindel, varscan2
- SYNE2 | c.13267G>A p.E4423K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1274876256; called by muse, mutect2, varscan2
- TBC1D32 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.318); catalogued as COSV51550688; called by muse, mutect2, varscan2
- TNRC6B | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.997); catalogued as COSV57289951; called by muse, mutect2, varscan2
- TPTE | c.646G>A p.E216K (on ENST00000618007 / NM_199261.4; = p.E198K on NM_199259.4) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs1568981033; called by muse, mutect2, varscan2
- TTN | c.40099G>A p.E13367K (on ENST00000591111; = p.E5943K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | PolyPhen probably damaging (0.994); catalogued as COSV59943060; called by muse, mutect2, varscan2
- ZNF208 | c.505G>T p.G169* | Nonsense Mutation (SNP) | VAF 27/132 reads (20%) | catalogued as COSV68113998; called by muse, mutect2, varscan2
- ZNF350 | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs150778438; called by muse, mutect2, varscan2
- ZNF429 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61915445; called by muse, mutect2, varscan2
- ZNF512B | c.2410C>A p.L804M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as COSV53879489; called by muse, mutect2, varscan2
- ACTR6 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS9 | c.1341C>A p.N447K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ADGRG4 | c.3500C>T p.T1167I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- AOC3 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- APOE | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- ARHGAP39 | c.813_816dup p.S273Afs*38 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ATN1 | c.1864G>C p.A622P | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ATP13A1 | c.1395A>G p.E465= | Splice Region (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- B3GNT5 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- BRD4 | c.1616A>G p.K539R | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- C16orf78 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CACNA1H | c.4477G>A p.A1493T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- CCDC62 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- CENPE | c.5099T>C p.V1700A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD5 | c.2436+1G>A p.X812_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- CLINT1 | c.1703A>G p.N568S | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- COBLL1 | c.1351C>T p.P451S (on ENST00000392717; = p.P413S on NM_014900.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CORO2B | c.292T>A p.F98I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXADR | c.1096T>C p.*366Qext*19 | Nonstop Mutation (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- DDAH2 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- DNM1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- E2F3 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- EIF4G2 | c.2381C>G p.S794C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ERCC4 | c.1811+2C>A p.X604_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- FMN1 | c.3938A>T p.E1313V (on ENST00000616417 / NM_001277313.2; = p.E1090V on NM_001103184.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FMN1 | c.3937G>T p.E1313* (on ENST00000616417 / NM_001277313.2; = p.E1090* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- GFM1 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR89A | c.282dup p.G95Wfs*13 | Frame Shift Ins (INS) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- GTF2F1 | c.1370A>C p.D457A | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- HACD2 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- HDAC4 | c.3086G>C p.R1029P | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HMCN1 | c.13653G>C p.K4551N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); called by muse, mutect2
- ICE1 | c.5656G>T p.E1886* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- ISM1 | c.1298dup p.Y433* | Nonsense Mutation (INS) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- KDF1 | c.648C>G p.Y216* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | called by muse, varscan2
- KIF2C | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- KTN1 | c.2777C>T p.S926L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by mutect2, varscan2
- LLGL1 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRC1 | c.1845G>C p.L615F | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MYO7B | c.2026C>T p.R676* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- NIN | c.3707A>T p.K1236M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- NLRC3 | c.2933T>C p.I978T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR2M4 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PAPPA2 | c.1720A>C p.N574H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- PARP10 | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 47/101 reads (47%) | called by muse, mutect2, varscan2
- PLBD1 | c.1288T>G p.L430V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- PLEKHA8 | c.1434G>C p.Q478H | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRB4 | c.387C>A p.N129K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.267); called by muse, varscan2
- PTGER2 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RABIF | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- RBM4 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBMS3 | c.889_894del p.X297_splice | Splice Site (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- RFX3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RNF6 | c.1963C>G p.H655D | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RPS6KA5 | c.1873C>G p.H625D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SACS | c.3429A>T p.Q1143H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SATB2 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SEMA4B | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC6 | c.1003T>C p.F335L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- STK17B | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STX17 | c.374C>G p.T125S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLL2 | c.2378C>A p.P793H | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOM1 | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRAF3 | c.1170G>C p.Q390H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRAK1 | c.2790G>A p.M930I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TSGA10 | c.1923-1G>A p.X641_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- UBQLN2 | c.683del p.P228Qfs*3 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- UBR4 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZNF428 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF582 | c.1128T>A p.F376L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVR1C | c.1374G>A p.G458= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- ADD2 | c.1971G>A p.T657= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs540699345, COSV100035555; called by muse, mutect2, varscan2
- AKR1A1 | c.977G>A p.*326= | Silent (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- C3 | c.2637G>A p.K879= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV55576433; called by muse, mutect2, varscan2
- CCDC58 | c.348G>A p.L116= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- CFP | c.792C>T p.G264= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs935477014; called by muse, mutect2, varscan2
- COL4A3 | c.438C>T p.I146= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs1171360432, COSV101170467; called by muse, mutect2, varscan2
- CXCR4 | c.510C>T p.P170= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV54009895; called by muse, mutect2, varscan2
- DEUP1 | c.1389G>A p.E463= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- DIP2A | c.2715C>T p.L905= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs369236341; called by muse, mutect2, varscan2
- ENO1 | c.246G>A p.L82= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99318675; called by muse, mutect2, varscan2
- F2 | c.1257G>A p.E419= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- FAM162A | c.126A>C p.T42= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- FBN1 | c.102G>A p.V34= | Silent (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- GTF3C1 | c.4686C>T p.D1562= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs576044105, COSV62243185; called by muse, mutect2, varscan2
- HNRNPA0 | c.318A>G p.K106= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs1240785321; called by muse, mutect2, varscan2
- IGKV1D-16 | c.237G>T p.G79= | Silent (SNP) | VAF 58/151 reads (38%) | catalogued as rs757157192; called by muse, mutect2, varscan2
- MAP3K5 | c.711C>T p.L237= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs1337259046; called by muse, mutect2, varscan2
- NWD1 | c.2505G>A p.Q835= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- PSMD11 | c.1155G>C p.L385= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- PTPRF | c.3792G>A p.V1264= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV63446284; called by muse, mutect2, varscan2
- PTPRO | c.3399C>T p.I1133= (on ENST00000281171 / NM_030667.3; = p.I1105= on NM_002848.4) | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- RFFL | c.282A>G p.T94= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- RYR2 | c.9303G>A p.L3101= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV63680964; called by muse, mutect2, varscan2
- SERTAD3 | c.429G>A p.G143= | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- SETD7 | c.318C>T p.F106= | Silent (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- SLC12A7 | c.1386G>A p.T462= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs762714893; called by mutect2, varscan2
- TIGD3 | c.1377C>T p.Y459= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs750375970; called by muse, mutect2, varscan2
- URGCP | c.1617G>A p.Q539= (on ENST00000453200 / NM_001077663.3; = p.Q530= on NM_017920.4) | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs753717943, COSV56247747; called by muse, mutect2, varscan2
- ZNF772 | c.1035T>A p.T345= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV58411540; called by muse, mutect2, varscan2
- ZSCAN25 | c.861G>A p.A287= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs773315356; called by muse, mutect2, varscan2
- ZZEF1 | c.2916A>G p.L972= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs754281701; called by muse, varscan2
